Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0VV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0VV-01A (Primary Tumor).

1CD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 lw 5/11

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.

LMP DATE: Postmenopausal.

PROCEDURE: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, pelvic and paraortic lymph node dissection.

SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION THERAPY: No.

OTHER DISEASES: No.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

	SPECIMENS
TUMOR TYPE:	Endometrioid adenocarcinoma, NOS
HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:	Well differentiated (FIGO 1)
ARCHITECTURAL GRADE:	Well differentiated
NUCLEAR GRADE:	Grade 1
TUMOR SIZE:	Maximum dimension: 25 mm
PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:	
DEPTH OF INVASION:	Anterior endomyometrium: 30 %, Posterior endomyometrium: 30 %
MARGINS OF RESECTION:	Less than 1/2 thickness of myometrium
ANGIOLYMPHATIC INVASION:	Vaginal margin is negative for tumor, Parametrium margin is negative for tumor
PRE-NEOPLASTIC CONDITIONS:	No
OTHER:	Complex endometrial hyperplasia without atypia
LYMPH NODES POSITIVE:	Adenomyosis, Leiomyoma
LYMPH NODES EXAMINED:	Number of lymph nodes positive:: 0
T STAGE, PATHOLOGIC:	Total number of lymph nodes examined: 9
N STAGE, PATHOLOGIC:	pT1a
M STAGE, PATHOLOGIC:	pN0
FIGO STAGE:	Not applicable
	IA

UUID: 42E7DSFF-18CD-4DEA-9518-9B9732BCA635

HI/AA Discrepancy		☒

Source: NCI Genomic Data Commons file d88aae40-bf2c-40c7-b230-f2603ccab4c5 (TCGA-BG-A0VV.42E7D5FF-18CD-4DEA-9518-9B9732BCA635.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).